Somatic mutation profile of tumor specimen TCGA-EM-A3SZ-01A (aliquot TCGA-EM-A3SZ-01A-11D-A22Z-08) from TCGA case TCGA-EM-A3SZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.9 years (15,659 days).
Specimen TCGA-EM-A3SZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f9a9fecb-4faf-4a8c-a04c-22c1acfcab04.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EM-A3SZ-10A (Blood Derived Normal), aliquot TCGA-EM-A3SZ-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/94b699cf-d78c-45cf-9ee2-8a72f0e4ca8b

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Frame Shift Ins 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABLIM2 | c.1644C>G p.I548M (on ENST00000341937 / NM_001130084.2; = p.I458M on NM_032432.5) | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1036980550, COSV99590285; called by muse, mutect2, varscan2
- CRISPLD2 | c.360-1G>A p.X120_splice | Splice Site (SNP) | VAF 18/42 reads (43%) | catalogued as COSV99295953; called by muse, mutect2, varscan2
- MAGEC1 | c.1424A>T p.Q475L | Missense Mutation (SNP) | VAF 84/266 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.075); catalogued as COSV99596305; called by muse, varscan2
- MORN5 | c.399G>T p.R133S | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as COSV101055972; called by muse, mutect2
- NAA30 | c.858G>T p.M286I | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100035995; called by muse, mutect2, varscan2
- TLN2 | c.6710C>A p.A2237D | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.858); catalogued as COSV100169846; called by muse, mutect2, varscan2
- TRIM33 | c.2088A>C p.L696F | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.018); catalogued as COSV100635656; called by muse, mutect2, varscan2
- VANGL1 | c.1448T>G p.L483R | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100049431; called by muse, mutect2, varscan2
- ZNF234 | c.530C>A p.T177K | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT tolerated (0.75); PolyPhen probably damaging (0.94); catalogued as COSV101468403; called by muse, mutect2, varscan2
- ZNF37A | c.1112C>G p.T371S | Missense Mutation (SNP) | VAF 4/80 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV100697424; called by muse, mutect2
- ZNF629 | c.1167G>T p.L389F | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99354991; called by muse, mutect2
- MRGPRX4 | c.560del p.L187Yfs*25 | Frame Shift Del (DEL) | VAF 13/132 reads (10%) | called by pindel, varscan2
- ZNF639 | c.1163dup p.N388Kfs*3 | Frame Shift Ins (INS) | VAF 21/128 reads (16%) | called by mutect2, pindel, varscan2
- ABCA4 | c.2862C>T p.Y954= | Silent (SNP) | VAF 18/185 reads (10%) | catalogued as rs757870374, COSV64671130; called by muse, mutect2
- TLE4 | c.789A>G p.P263= | Silent (SNP) | VAF 29/84 reads (35%) | catalogued as rs1274905527, COSV99512908; called by muse, mutect2, varscan2
